Somatic mutation profile of tumor specimen C3L-00145-02 (aliquot CPT0002630009) from CPTAC case C3L-00145, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 60.0 years (21,900 days).
Specimen C3L-00145-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a93f017a-7b85-43dc-9ffa-f4d4bd9e31fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00145-71 (Blood Derived Normal), aliquot CPT0007990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5dbb770-7460-4b58-9625-fee9e483bee3

The open-access MAF lists 63 somatic variants for this specimen: 36 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 16, Intron 6, Nonsense Mutation 4, Frame Shift Ins 3, In Frame Del 3, 5'UTR 2, 5'Flank 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 89/429 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 20/91 reads (22%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 17/254 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.723dup p.E242* | Frame Shift Ins (INS) | VAF 125/348 reads (36%) | catalogued as rs1060500115; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGBL1 | c.3166C>T p.Q1056* | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | catalogued as rs768831404; called by muse, mutect2, varscan2
- ARC | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs758031109; called by muse, mutect2, varscan2
- ATP13A2 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763632781; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNBP | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV69654485; called by muse, mutect2, varscan2
- CUL4B | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.65); catalogued as COSV60686098; called by muse, mutect2
- GALR1 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55315950; called by muse, mutect2, varscan2
- IGSF1 | c.3274C>A p.P1092T | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.21); catalogued as COSV100811823; called by muse, mutect2, varscan2
- JAM2 | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100467726; called by muse, mutect2, varscan2
- KCP | c.2339G>A p.R780H (on ENST00000620378; = p.R840H on NM_001366122.1) | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs935377722, COSV99926061; called by muse, varscan2
- MFRP | c.214G>A p.D72N (on ENST00000449574; = p.D448N on NM_031433.4) | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs142846614; called by muse, mutect2, varscan2
- MINK1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as COSV61791654; called by muse, mutect2, varscan2
- OR1N1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs370443121; called by muse, mutect2, varscan2
- PCDHB3 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.157); catalogued as COSV50566113; called by muse, mutect2
- TUBA3C | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs962584103, COSV101262793, COSV67138827; called by muse, mutect2, varscan2
- ZC3H13 | c.4033C>T p.R1345* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as rs773278636, COSV54447432; called by muse, mutect2, varscan2
- ZNF385C | c.37_39del p.K13del | In Frame Del (DEL) | VAF 4/56 reads (7%) | catalogued as rs1567992475; called by mutect2, pindel
- ABI3BP | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTCF | c.1095dup p.L366Ifs*43 | Frame Shift Ins (INS) | VAF 10/77 reads (13%) | called by mutect2, pindel
- DENND2C | c.2159G>A p.W720* (on ENST00000393274 / NM_001256404.2; = p.W663* on NM_198459.4) | Nonsense Mutation (SNP) | VAF 30/171 reads (18%) | called by muse, mutect2, varscan2
- DICER1 | c.5549C>A p.P1850H | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLG2 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 65/300 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HEPH | c.2050A>T p.M684L (on ENST00000343002; = p.M417L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IQSEC2 | c.2803C>T p.R935C (on ENST00000642864 / NM_001111125.3; = p.R730C on NM_015075.2) | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- MAPK14 | c.379_381del p.V127del | In Frame Del (DEL) | VAF 6/88 reads (7%) | called by mutect2, pindel
- MED1 | c.2450A>G p.Q817R | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- MTOR | c.4955C>G p.T1652S | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NHS | c.4196T>G p.L1399R | Missense Mutation (SNP) | VAF 14/447 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- NUAK2 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRAMEF12 | c.245dup p.E83Gfs*4 | Frame Shift Ins (INS) | VAF 14/90 reads (16%) | called by mutect2, pindel
- SH3D21 | c.2046A>T p.E682D (on ENST00000453908 / NM_001162530.2; = p.E571D on NM_024676.5) | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SNRNP70 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TBL2 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- AGRN | c.4167C>T p.R1389= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs74726601; called by muse, mutect2, varscan2
- CCDC40 | c.1527C>T p.R509= | Silent (SNP) | VAF 90/528 reads (17%) | catalogued as rs1245224235; called by muse, mutect2, varscan2
- CLEC4D | c.432A>C p.G144= | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as rs1382155805, COSV55231158; called by muse, mutect2, varscan2
- COL4A1 | c.1419C>T p.D473= | Silent (SNP) | VAF 38/266 reads (14%) | catalogued as rs140440365, COSV65422031, COSV65423996; called by muse, mutect2, varscan2
- DCDC1 | c.3012T>C p.C1004= (on ENST00000597505 / NM_001367979.1; = p.C111= on NM_020869.3) | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- DPPA2 | c.546G>A p.P182= | Silent (SNP) | VAF 39/377 reads (10%) | catalogued as rs752711484, COSV101524757; called by muse, mutect2, varscan2
- GDPD3 | c.123G>A p.L41= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- GLRA4 | c.372G>T p.L124= | Silent (SNP) | VAF 73/350 reads (21%) | called by muse, mutect2, varscan2
- GRIA3 | c.1473C>T p.N491= | Silent (SNP) | VAF 39/247 reads (16%) | catalogued as rs139327479, COSV52054361; called by muse, mutect2, varscan2
- OR8J3 | c.729G>T p.S243= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs774862778, COSV56879581, COSV56879736; called by muse, mutect2, varscan2
- PCDHB15 | c.1422C>T p.S474= | Silent (SNP) | VAF 18/626 reads (3%) | called by muse, mutect2
- PEX5L | c.1014G>A p.K338= | Silent (SNP) | VAF 39/276 reads (14%) | called by muse, mutect2, varscan2
- RBAK | c.1269C>T p.H423= | Silent (SNP) | VAF 58/221 reads (26%) | catalogued as rs757814540; called by muse, mutect2, varscan2
- SRCIN1 | c.723C>T p.H241= (on ENST00000621492; = p.H207= on NM_025248.3) | Silent (SNP) | VAF 58/367 reads (16%) | catalogued as rs573766396; called by muse, mutect2, varscan2
- TMC4 | c.1056C>T p.N352= (on ENST00000617472 / NM_001145303.3; = p.N346= on NM_144686.4) | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as rs1215252459; called by muse, mutect2, varscan2
- TRADD | c.873G>A p.E291= | Silent (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-10230C>T | Intron (SNP) | VAF 29/140 reads (21%) | catalogued as rs1554290450; called by muse, mutect2, varscan2
- ANKRD11 | c.87+3411G>T | Intron (SNP) | VAF 47/202 reads (23%) | called by muse, mutect2, varscan2
- ANO1 | c.1950+44C>G | Intron (SNP) | VAF 64/305 reads (21%) | catalogued as rs771056081; called by muse, mutect2, varscan2
- BAD | c.*361A>G | 3'UTR (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- CCDC107 | chr9:35657874 G>T | 5'Flank (SNP) | VAF 56/293 reads (19%) | called by muse, mutect2, varscan2
- CEACAM19 | c.-6G>A | 5'UTR (SNP) | VAF 16/194 reads (8%) | catalogued as rs377367864; called by muse, mutect2
- EYS | c.1766+35T>C | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- KCNMA1 | c.2267-49A>T | Intron (SNP) | VAF 23/236 reads (10%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1748C>T | Intron (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- Z97192.4 | chr22:49657328 G>A | 3'Flank (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- ZNF708 | c.-29A>T | 5'UTR (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
